Somatic mutation profile of tumor specimen TCGA-VQ-A8E3-01A (aliquot TCGA-VQ-A8E3-01A-11D-A397-08) from TCGA case TCGA-VQ-A8E3, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 79.2 years (28,919 days).
Specimen TCGA-VQ-A8E3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a2c8217-42ab-423c-ad7f-a28e4aee631b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A8E3-10A (Blood Derived Normal), aliquot TCGA-VQ-A8E3-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ac10ba2-57be-4cbb-9244-af4252471934

The open-access MAF lists 867 somatic variants for this specimen: 675 protein-altering or splice-affecting, 168 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 440, Silent 168, Frame Shift Del 146, Frame Shift Ins 34, Nonsense Mutation 25, Splice Site 15, Intron 10, Splice Region 8, In Frame Del 6, RNA 6, 3'UTR 5, 3'Flank 2.

Variants (750 of 867; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCHE | c.1027dup p.T343Nfs*8 | Frame Shift Ins (INS) | VAF 10/54 reads (19%) | catalogued as rs754214624; ClinVar: likely pathogenic; called by mutect2, varscan2
- CFTR | c.850del p.M284* | Frame Shift Del (DEL) | VAF 23/92 reads (25%) | catalogued as rs786204693; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CFTR | c.2125C>T p.R709* | Nonsense Mutation (SNP) | VAF 16/62 reads (26%) | catalogued as rs121908760, CM950248, COSV50041819, COSV99140454; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2C | c.13646G>A p.R4549H | Missense Mutation (SNP) | VAF 17/67 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51504408; called by muse, mutect2, varscan2
- OFD1 | c.710del p.K237Sfs*6 | Frame Shift Del (DEL) | VAF 18/32 reads (56%) | catalogued as rs312262845; ClinVar: pathogenic; called by mutect2, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 13/30 reads (43%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PDZD7 | c.166dup p.R56Pfs*24 | Frame Shift Ins (INS) | VAF 20/79 reads (25%) | catalogued as rs587776894; ClinVar: pathogenic / risk factor; called by mutect2, varscan2
- TP53 | c.437G>A p.W146* | Nonsense Mutation (SNP) | VAF 34/45 reads (76%) | hotspot (GDC flag); catalogued as rs1206165503, CM107391, COSV52661900, COSV52703354, COSV52753201; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.484-2A>C p.X162_splice | Splice Site (SNP) | VAF 17/76 reads (22%) | catalogued as COSV100229315; called by muse, mutect2, varscan2
- A2ML1 | c.3116C>T p.A1039V | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769398333, COSV55285108; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AARS2 | c.2607del p.T871Lfs*13 | Frame Shift Del (DEL) | VAF 22/78 reads (28%) | catalogued as rs771808127, COSV55113098; called by mutect2, pindel, varscan2
- ABCA1 | c.518T>C p.L173P | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.62); catalogued as rs775953765, COSV101035734; called by muse, mutect2, varscan2
- ABCC5 | c.561G>A p.M187I | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99657410; called by muse, mutect2, varscan2
- ABCC8 | c.2943G>T p.E981D | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100217624; called by muse, mutect2, varscan2
- ABCF1 | c.2267T>C p.L756P (on ENST00000326195 / NM_001025091.2; = p.L718P on NM_001090.3) | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100401004; called by muse, mutect2, varscan2
- ABCG8 | c.1696C>A p.L566I | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.212); catalogued as COSV99700167; called by muse, mutect2
- ACBD4 | c.268A>G p.T90A | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.017); catalogued as COSV100416288; called by muse, mutect2, varscan2
- ACSF3 | c.1012C>A p.P338T | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.817); catalogued as COSV100441513; called by muse, mutect2, varscan2
- ADAM33 | c.1043G>A p.G348D | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100598040; called by muse, mutect2, varscan2
- ADAMTS13 | c.1832T>C p.I611T | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as COSV100747185; called by muse, mutect2, varscan2
- ADAR | c.3533T>C p.L1178P | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99426567; called by muse, mutect2, varscan2
- ADGRB1 | c.1144G>A p.V382M | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as rs773821198, COSV100029353; called by muse, mutect2
- ADGRE5 | c.2485A>G p.R829G (on ENST00000242786 / NM_078481.4; = p.R736G on NM_001784.5) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV99660474; called by muse, mutect2, varscan2
- ADSS1 | c.845C>T p.T282M | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs542060225, COSV100272132; called by muse, mutect2, varscan2
- AEBP1 | c.1349G>A p.R450K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as rs1306342939, COSV99789033; called by muse, mutect2, varscan2
- AFF3 | c.3457C>T p.R1153C | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57851371; called by muse, mutect2, varscan2
- AIP | c.658T>C p.S220P | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as COSV99653795; called by muse, mutect2, varscan2
- ALK | c.4691C>T p.A1564V | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.313); catalogued as COSV101202111; called by muse, mutect2, varscan2
- ALPI | c.1325C>T p.A442V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1158171138, COSV55013640; called by muse, mutect2, varscan2
- ALS2 | c.3931C>T p.Q1311* | Nonsense Mutation (SNP) | VAF 49/176 reads (28%) | catalogued as COSV99969906; called by muse, mutect2, varscan2
- AMER2 | c.601A>G p.M201V | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV100766362; called by muse, mutect2, varscan2
- AMFR | c.444G>A p.W148* | Nonsense Mutation (SNP) | VAF 32/91 reads (35%) | catalogued as rs765166104, COSV99316169; called by muse, mutect2, varscan2
- ANAPC1 | c.4883C>T p.T1628M | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.093); catalogued as rs751341287, COSV100595015; called by mutect2, varscan2
- ANK2 | c.8336C>T p.A2779V | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); catalogued as COSV100003593; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4594del p.R1532Gfs*5 | Frame Shift Del (DEL) | VAF 48/187 reads (26%) | catalogued as COSV51845823; called by mutect2, pindel, varscan2
- ANKIB1 | c.437del p.N146Tfs*12 | Frame Shift Del (DEL) | VAF 13/52 reads (25%) | catalogued as rs201434379; called by mutect2, varscan2
- ANKRD12 | c.3766_3768del p.P1256del | In Frame Del (DEL) | VAF 32/137 reads (23%) | catalogued as rs757311943; called by mutect2, pindel, varscan2
- ANKRD26 | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs373943537; called by muse, mutect2, varscan2
- ANKRD54 | c.871A>G p.S291G | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV53236589; called by muse, mutect2
- ANKRD55 | c.1739C>A p.P580H | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.96); catalogued as COSV100591556; called by muse, mutect2, varscan2
- ANKS3 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.207); catalogued as rs142015202, COSV100423251; called by muse, mutect2, varscan2
- AP1G2 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV58115734; called by muse, mutect2, varscan2
- AP3D1 | c.3092C>T p.A1031V | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs370612433; called by muse, mutect2
- APBA2 | c.2178+1G>A p.X726_splice | Splice Site (SNP) | VAF 11/39 reads (28%) | catalogued as COSV101382484; called by muse, mutect2, varscan2
- APLNR | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 50/82 reads (61%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.466); catalogued as rs767906014, COSV99951615; called by muse, mutect2, varscan2
- APOB | c.8447A>C p.N2816T | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99267362; called by muse, mutect2, varscan2
- APP | c.379C>A p.L127I | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100696178; called by muse, mutect2, varscan2
- ARAP2 | c.87G>C p.E29D | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV58288129; called by muse, mutect2, varscan2
- ARHGAP22 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 49/214 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99985828; called by muse, mutect2, varscan2
- ARID1A | c.5548dup p.D1850Gfs*4 | Frame Shift Ins (INS) | VAF 18/56 reads (32%) | catalogued as rs758608743; called by mutect2, varscan2
- ARID2 | c.1150G>C p.A384P | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.942); catalogued as COSV100536813; called by muse, mutect2, varscan2
- ARL13A | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs553228239, COSV65880071; called by muse, mutect2, varscan2
- ASAP2 | c.2701C>A p.P901T | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV55636236; called by mutect2, varscan2
- ASPH | c.1384G>A p.V462M | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200072789; called by muse, mutect2, varscan2
- ASTN1 | c.1598+1G>A p.X533_splice | Splice Site (SNP) | VAF 18/87 reads (21%) | catalogued as COSV99922749; called by muse, mutect2, varscan2
- ATP10A | c.4276del p.L1426Cfs*66 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | catalogued as rs768534594; called by mutect2, pindel, varscan2
- ATP9A | c.1922T>A p.M641K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV100125497; called by muse, mutect2, varscan2
- ATRNL1 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100746747; called by muse, mutect2, varscan2
- AVL9 | c.1762C>T p.R588C | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs762532514, COSV100594759; called by muse, mutect2, varscan2
- AVPR1B | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs1157916034, COSV100899439; called by muse, mutect2, varscan2
- BAMBI | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs201458451, COSV100977536; called by muse, mutect2, varscan2
- BCAN | c.2551C>T p.R851C | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs749535108, COSV100228391; called by muse, mutect2, varscan2
- BCOR | c.3654G>T p.W1218C (on ENST00000378444 / NM_001123385.2; = p.W1184C on NM_017745.6) | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100653876; called by muse, mutect2, varscan2
- BET1 | c.168A>T p.E56D | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV55993178, COSV99747377; called by muse, mutect2, varscan2
- BOD1L1 | c.7898C>A p.P2633H | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV99240142; called by muse, mutect2, varscan2
- BORCS5 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.158); catalogued as COSV100056309; called by muse, mutect2, varscan2
- BPTF | c.5590C>T p.R1864* | Nonsense Mutation (SNP) | VAF 29/99 reads (29%) | catalogued as COSV58831921; called by muse, mutect2, varscan2
- BRAT1 | c.647A>G p.Q216R | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV100500632; called by muse, mutect2, varscan2
- BRD1 | c.3134G>A p.R1045H (on ENST00000216267 / NM_001349940.1; = p.R1176H on NM_001304808.3) | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1184710013, COSV53462997; called by muse, mutect2, varscan2
- BRD4 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 44/200 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.046); catalogued as COSV99651258; called by muse, mutect2, varscan2
- BSG | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.036); catalogued as rs748351801, COSV100344975; called by muse, mutect2, varscan2
- BSN | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV56526174; called by muse, mutect2, varscan2
- BSN | c.10436C>T p.A3479V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs201323732; called by muse, mutect2, varscan2
- BTNL8 | c.1418A>G p.Q473R | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as COSV99180561; called by muse, mutect2, varscan2
- C11orf49 | c.584A>G p.E195G | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV99562609; called by muse, mutect2, varscan2
- C19orf57 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV100694831; called by muse, mutect2, varscan2
- C1QTNF2 | c.416G>A p.G139E (on ENST00000393975; = p.G94E on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67433500; called by muse, mutect2, varscan2
- C1orf210 | c.68G>A p.G23D | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.261); catalogued as rs1050826984, COSV101382230; called by muse, mutect2, varscan2
- C1orf94 | c.1276G>A p.A426T (on ENST00000488417 / NM_001134734.2; = p.A236T on NM_032884.5) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.042); catalogued as rs759549703, COSV64913367; called by muse, mutect2, varscan2
- C20orf194 | c.2942G>A p.R981H | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs372426469; called by muse, mutect2, varscan2
- C20orf96 | c.408G>A p.M136I (on ENST00000360321 / NM_153269.3; = p.M135I on NM_080571.1) | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100826814; called by muse, mutect2, varscan2
- C7orf26 | c.1175C>A p.P392H | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1349041681, COSV100732983; called by muse, mutect2, varscan2
- CACNA1A | c.6173del p.P2058Lfs*70 | Frame Shift Del (DEL) | VAF 12/24 reads (50%) | catalogued as CD040162; called by mutect2, varscan2
- CACNA1E | c.3829G>A p.A1277T | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100704653; called by muse, mutect2, varscan2
- CACNA1I | c.938G>A p.S313N | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.996); catalogued as COSV100358848; called by muse, mutect2, varscan2
- CACNA1S | c.2245G>T p.E749* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100755281; called by muse, varscan2
- CACNA2D4 | c.1994C>T p.T665M | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs770622451, COSV99766352; called by muse, mutect2, varscan2
- CALHM5 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100635648; called by muse, mutect2
- CAMSAP3 | c.3572G>A p.R1191Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as rs779466647, COSV99351803; called by muse, mutect2, varscan2
- CAND2 | c.2234G>A p.R745H (on ENST00000456430 / NM_001162499.2; = p.R652H on NM_012298.3) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs755177838, COSV99929621, COSV99929636; called by muse, mutect2, varscan2
- CARD10 | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1377804818, COSV99325288; called by muse, mutect2, varscan2
- CASP4 | c.430A>G p.T144A | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.216); catalogued as COSV101274198; called by muse, mutect2, varscan2
- CBX4 | c.690dup p.N231Qfs*81 | Frame Shift Ins (INS) | VAF 42/110 reads (38%) | catalogued as rs772839792; called by mutect2, varscan2
- CCDC138 | c.1801A>G p.S601G | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV99719425; called by muse, mutect2, varscan2
- CCDC151 | c.1772G>A p.R591H | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100710618; called by muse, mutect2, varscan2
- CCDC40 | c.3296G>A p.R1099H | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as rs759177015, COSV56407615, COSV56411302; called by muse, mutect2, varscan2
- CCDC8 | c.794G>T p.W265L | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); catalogued as COSV100282147; called by muse, mutect2, varscan2
- CCNY | c.812A>G p.Y271C | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as COSV99590992; called by muse, mutect2, varscan2
- CCT2 | c.1054G>A p.V352I | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100167780; called by muse, mutect2, varscan2
- CD247 | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV62978662; called by muse, mutect2, varscan2
- CDC14A | c.203A>G p.N68S | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as rs757576834, COSV100325800; called by muse, mutect2, varscan2
- CDC14A | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100325805; called by muse, mutect2, varscan2
- CDC16 | c.953A>G p.H318R | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.09); catalogued as COSV99373109; called by muse, mutect2, varscan2
- CDH10 | c.1601A>G p.N534S | Missense Mutation (SNP) | VAF 54/233 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as COSV100052733; called by muse, mutect2, varscan2
- CDRT1 | c.2027G>A p.S676N | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100599967; called by muse, mutect2, varscan2
- CELF6 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.196); catalogued as rs760953520, COSV99764073; called by muse, mutect2, varscan2
- CELSR1 | c.2848A>G p.I950V | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.76); PolyPhen benign (0.14); catalogued as COSV99419655; called by muse, mutect2, varscan2
- CELSR3 | c.2675G>A p.R892H | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771709882, COSV50884054; called by muse, mutect2, varscan2
- CEP192 | c.7390C>T p.R2464* | Nonsense Mutation (SNP) | VAF 29/80 reads (36%) | catalogued as rs781480656, COSV58069822; called by muse, mutect2, varscan2
- CEP250 | c.6449G>A p.R2150Q | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as rs759294916, COSV61173572; called by muse, mutect2, varscan2
- CFAP100 | c.194T>C p.L65P | Missense Mutation (SNP) | VAF 123/255 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100729379; called by muse, mutect2, varscan2
- CFAP20DC | c.1004T>C p.V335A (on ENST00000482387 / NM_001351530.2; = p.V210A on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV99919374; called by muse, mutect2, varscan2
- CFAP58 | c.2321C>T p.A774V | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.271); catalogued as rs780236532, COSV63834380; called by muse, mutect2
- CFHR4 | c.1345A>G p.T449A (on ENST00000367416 / NM_001201551.2; = p.T203A on NM_006684.5) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.013); catalogued as COSV99261213; called by muse, mutect2, varscan2
- CHAT | c.1408C>T p.R470* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as rs142889639, CM130380; called by muse, mutect2, varscan2
- CHD6 | c.5428T>G p.L1810V | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV100951306; called by muse, mutect2, varscan2
- CHD6 | c.2743C>T p.R915C | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58557654; called by muse, mutect2, varscan2
- CHMP1B | c.261G>T p.K87N | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV99304060; called by muse, mutect2, varscan2
- CHTF18 | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs377268098; called by muse, varscan2
- CLCA4 | c.1810G>A p.V604I | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs377379798; called by muse, mutect2, varscan2
- CLEC12A | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs753409256, COSV100429646; called by muse, mutect2, varscan2
- CLEC4C | c.595C>T p.H199Y | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV100665547; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 58/153 reads (38%) | catalogued as rs369752219; called by mutect2, varscan2
- CLSPN | c.1525C>T p.R509W | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs200314953, COSV99231393; called by muse, mutect2, varscan2
- CNBD1 | c.1187T>C p.L396P | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV73072298, COSV73072404, COSV73073941; called by muse, mutect2, varscan2
- CNGB1 | c.1501C>T p.L501F | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1275418233, COSV99208154, COSV99212273; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | catalogued as rs374805044; called by mutect2, varscan2
- COL18A1 | c.5075A>G p.H1692R (on ENST00000359759 / NM_130444.3; = p.H1457R on NM_030582.4) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100229605; called by muse, mutect2, varscan2
- COL23A1 | c.958A>G p.K320E | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as COSV101179588; called by muse, varscan2
- COL5A1 | c.669G>T p.Q223H | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100880430; called by muse, mutect2, varscan2
- COL5A1 | c.5263G>A p.A1755T | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.245); catalogued as rs776748227, COSV65664867, COSV65666442; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- COL9A3 | c.1777G>A p.G593R | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1007898382, COSV100101717, COSV58986363; called by muse, mutect2, varscan2
- COLEC10 | c.336del p.G113Afs*30 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | catalogued as rs1286976627; called by mutect2, pindel, varscan2
- COLGALT1 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as rs775756264, COSV99395037; called by muse, mutect2, varscan2
- COPA | c.2233C>T p.R745C | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs763748181, COSV54110045; called by muse, mutect2, varscan2
- CPB1 | c.1013T>G p.L338R | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99294468; called by muse, mutect2
- CRMP1 | c.1207G>A p.V403M | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as rs752604466, COSV61478781; called by muse, mutect2, varscan2
- CRTC2 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100135667; called by muse, mutect2, varscan2
- CSPG4 | c.1328del p.G443Afs*16 | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | catalogued as rs772622628; called by mutect2, pindel, varscan2
- CTU2 | c.913C>T p.R305W | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370063135; called by muse, mutect2, varscan2
- CUBN | c.3857A>T p.Q1286L | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100913372; called by muse, mutect2, varscan2
- CX3CL1 | c.429_431del p.S144del | In Frame Del (DEL) | VAF 11/50 reads (22%) | catalogued as rs1194654332; called by pindel, varscan2
- CYP17A1 | c.177del p.K59Nfs*16 | Frame Shift Del (DEL) | VAF 16/94 reads (17%) | catalogued as rs1402132413; called by mutect2, pindel, varscan2
- CYP2E1 | c.83G>T p.S28I | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as COSV99429182; called by muse, mutect2, varscan2
- CYP2S1 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59505697; called by muse, mutect2
- CYRIB | c.476A>G p.Y159C | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1225519809, COSV101310289; called by muse, mutect2, varscan2
- DCAF17 | c.1231del p.S411Vfs*23 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | catalogued as rs755674655; called by mutect2, varscan2
- DCAF4 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as rs1444266836, COSV100611152; called by muse, mutect2, varscan2
- DDB1 | c.545A>G p.Y182C | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1016945831, COSV100074801; called by muse, mutect2, varscan2
- DDX17 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.108); catalogued as COSV99318944; called by muse, mutect2, varscan2
- DDX46 | c.2231C>T p.A744V | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV100844916; called by muse, mutect2, varscan2
- DDX49 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs747592114, COSV99447794; called by muse, mutect2, varscan2
- DDX60 | c.2731C>T p.R911* | Nonsense Mutation (SNP) | VAF 11/46 reads (24%) | catalogued as rs760941649, COSV67098215; called by muse, mutect2, varscan2
- DHPS | c.709dup p.T237Nfs*25 | Frame Shift Ins (INS) | VAF 10/28 reads (36%) | catalogued as rs756762989; called by pindel, varscan2
- DHX29 | c.2690G>A p.R897Q | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); catalogued as rs1049487959, COSV52419059; called by muse, mutect2, varscan2
- DHX30 | c.19T>A p.F7I | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.879); catalogued as COSV100820098; called by muse, mutect2
- DIDO1 | c.3541+6C>T | Splice Region (SNP) | VAF 10/53 reads (19%) | catalogued as rs765548395, COSV56621287; called by muse, mutect2, varscan2
- DIMT1 | c.761del p.N254Tfs*12 | Frame Shift Del (DEL) | VAF 15/84 reads (18%) | catalogued as rs757109196; called by mutect2, pindel, varscan2
- DLD | c.1454A>G p.H485R | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99227427; called by muse, mutect2, varscan2
- DMXL2 | c.6230T>G p.L2077R | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99198332; called by muse, mutect2, varscan2
- DNAH11 | c.9665T>C p.V3222A | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769477190, COSV100180354; called by muse, mutect2, varscan2
- DNAJC30 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 12/64 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs781929643, COSV56095346; called by muse, mutect2, varscan2
- DNM2 | c.886C>A p.L296I | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.506); catalogued as COSV58961458, COSV58962551; called by muse, mutect2
- DOCK11 | c.5008A>T p.T1670S | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT tolerated (0.66); PolyPhen benign (0.276); catalogued as COSV99354521; called by muse, mutect2, varscan2
- DOK4 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs751229638, COSV100407657; called by muse, mutect2, varscan2
- DOP1B | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1424910802, COSV99535999; called by muse, mutect2, varscan2
- DPF1 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.06); catalogued as rs1257922405, COSV62792645; called by muse, mutect2, varscan2
- DST | c.19115T>A p.L6372Q (on ENST00000361203 / NM_001374722.1; = p.L4069Q on NM_015548.5) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99759135; called by muse, mutect2
- DSTN | c.308del p.L103Cfs*6 | Frame Shift Del (DEL) | VAF 21/106 reads (20%) | catalogued as rs750962255; called by mutect2, varscan2
- DYNC1H1 | c.9706G>A p.A3236T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100795283; called by muse, mutect2, varscan2
- E2F8 | c.842C>T p.T281M | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs755274793, COSV100001230; called by muse, mutect2, varscan2
- EBPL | c.516del p.F172Lfs*7 | Frame Shift Del (DEL) | VAF 21/53 reads (40%) | catalogued as rs369293935; called by mutect2, varscan2
- ECE1 | c.1782-2A>G p.X594_splice | Splice Site (SNP) | VAF 15/53 reads (28%) | catalogued as COSV99942241; called by muse, mutect2, varscan2
- ECM2 | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as rs769488943, COSV100755956; called by muse, mutect2, varscan2
- EGF | c.2018G>A p.G673D | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1253795861, COSV99491292; called by muse, mutect2, varscan2
- EGLN2 | c.314A>G p.Q105R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as COSV100393821; called by muse, mutect2, varscan2
- EIF4G2 | c.905T>C p.V302A | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as COSV101151080; called by muse, mutect2, varscan2
- EIF5 | c.182T>C p.L61P | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV99384987; called by muse, mutect2, varscan2
- EIPR1 | c.793G>A p.V265M | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs149049035; called by muse, mutect2, varscan2
- EML1 | c.716A>G p.Y239C | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99215528; called by muse, mutect2
- EOMES | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99841623; called by muse, mutect2, varscan2
- EPB41L3 | c.1669G>C p.D557H | Missense Mutation (SNP) | VAF 53/70 reads (76%) | SIFT deleterious (0.05); PolyPhen benign (0.319); catalogued as COSV100549994; called by muse, mutect2, varscan2
- EPB41L5 | c.802del p.W268Gfs*4 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | catalogued as rs35675992; called by mutect2, pindel, varscan2
- EPG5 | c.1925G>A p.R642Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1455631275, COSV56352125; called by muse, mutect2
- EPHB3 | c.2978C>T p.T993M | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as rs200546160, COSV100383229; called by muse, mutect2
- ERVW-1 | c.1409A>C p.N470T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV101423864; called by muse, mutect2
- ETV5 | c.232+1G>A p.X78_splice | Splice Site (SNP) | VAF 28/108 reads (26%) | catalogued as COSV60502537; called by muse, mutect2, varscan2
- EYA4 | c.1342A>G p.N448D (on ENST00000531901 / NM_001301013.1; = p.N442D on NM_004100.5) | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1198184114, COSV62061263; called by muse, mutect2, varscan2
- EZH2 | c.1823G>A p.R608Q (on ENST00000460911 / NM_001203247.2; = p.R613Q on NM_004456.5) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as rs561605379, COSV100236491; called by muse, mutect2, varscan2
- F5 | c.6164G>A p.R2055Q | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886045542, COSV100889208; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM114A2 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as COSV100697778; called by muse, mutect2, varscan2
- FAM214A | c.2042del p.N681Mfs*5 | Frame Shift Del (DEL) | VAF 11/58 reads (19%) | catalogued as rs762546731, COSV55927849; called by mutect2, varscan2
- FAM32A | c.305A>G p.H102R | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV99655332; called by muse, mutect2
- FAT4 | c.13898C>T p.S4633L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs771288110, COSV58674300, COSV58674409; called by muse, mutect2, varscan2
- FBXL4 | c.347G>A p.R116K | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.952); catalogued as COSV100014332; called by muse, mutect2, varscan2
- FBXO31 | c.1230G>T p.E410D | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100291575; called by muse, mutect2, varscan2
- FBXO46 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.996); catalogued as COSV100480364; called by muse, mutect2, varscan2
- FBXW9 | c.1085G>A p.R362H (on ENST00000587955; = p.R342H on NM_032301.3) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs766426225, COSV100982023; called by muse, mutect2, varscan2
- FCGBP | c.7837G>A p.A2613T | Missense Mutation (SNP) | VAF 24/285 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.079); catalogued as rs765323228; called by muse, mutect2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 18/98 reads (18%) | catalogued as rs748969702; called by mutect2, varscan2
- FFAR3 | c.863A>G p.H288R | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs759056809; called by mutect2, varscan2
- FGFR3 | c.*701G>A | Splice Region (SNP) | VAF 4/35 reads (11%) | catalogued as COSV99603159; called by muse, mutect2, varscan2
- FHDC1 | c.1315del p.T439Pfs*2 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | catalogued as rs1303890230; called by mutect2, varscan2
- FLII | c.3718C>T p.R1240C | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs563225941, COSV100375610; called by muse, mutect2, varscan2
- FOLH1 | c.1501del p.S501Vfs*12 | Frame Shift Del (DEL) | VAF 20/100 reads (20%) | catalogued as rs764290022, COSV57049642; called by mutect2, pindel, varscan2
- FOXP1 | c.1310G>T p.R437M | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV100562246; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 9/70 reads (13%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- GALNT14 | c.5G>A p.R2Q | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1002582670, COSV61107736; called by muse, mutect2, varscan2
- GALNT5 | c.797A>T p.N266I | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV52037663, COSV99375503; called by muse, mutect2, varscan2
- GALNT6 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs145549042; called by muse, mutect2, varscan2
- GBX1 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368877994, COSV52547601; called by muse, mutect2, varscan2
- GEMIN5 | c.1600-2A>G p.X534_splice | Splice Site (SNP) | VAF 13/47 reads (28%) | catalogued as COSV99594240; called by muse, mutect2, varscan2
- GIGYF2 | c.3650C>T p.P1217L | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as rs199779111, COSV101004583; called by muse, varscan2
- GLIS3 | c.601G>A p.G201S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs1227142847, COSV100174622; called by muse, mutect2, varscan2
- GNB1L | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs138225912; called by muse, mutect2, varscan2
- GOLGA3 | c.2696C>T p.A899V | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs149136461; called by muse, mutect2, varscan2
- GOLGB1 | c.406G>T p.D136Y | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); catalogued as COSV100511395; called by muse, mutect2, varscan2
- GOLT1A | c.52G>A p.G18S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149764346; called by muse, mutect2
- GPANK1 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1242017918, COSV100789044; called by muse, mutect2
- GPC3 | c.1458A>T p.K486N | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.136); catalogued as COSV100893471; called by muse, mutect2, varscan2
- GPR152 | c.1136C>T p.T379M | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as rs775290604, COSV100351625; called by muse, mutect2, varscan2
- GPR162 | c.1425dup p.L476Afs*36 (on ENST00000311268 / NM_019858.2; = p.L192Afs*36 on NM_014449.2) | Frame Shift Ins (INS) | VAF 32/97 reads (33%) | catalogued as rs781913714; called by mutect2, pindel, varscan2
- GPR37L1 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.527); catalogued as rs752647832, COSV100938583; called by muse, varscan2
- GPRIN1 | c.1165T>C p.S389P | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.608); catalogued as COSV99992068; called by muse, mutect2
- GRM8 | c.2158dup p.H720Pfs*5 | Frame Shift Ins (INS) | VAF 8/34 reads (24%) | catalogued as rs772717214; called by mutect2, varscan2
- GSG1L | c.824G>A p.R275Q (on ENST00000447459 / NM_001109763.2; = p.R120Q on NM_144675.2) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as rs376358621; called by muse, mutect2, varscan2
- GTF3C3 | c.1081del p.T361Lfs*26 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | catalogued as rs750792116; called by mutect2, varscan2
- H2AZ1 | c.124A>T p.T42S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.985); catalogued as COSV99597574; called by muse, mutect2, varscan2
- HBEGF | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 90/296 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.107); catalogued as rs1439134368, COSV99138284; called by muse, mutect2, varscan2
- HCLS1 | c.109C>T p.R37* | Nonsense Mutation (SNP) | VAF 27/120 reads (23%) | catalogued as rs781573878, COSV58854249; called by muse, mutect2, varscan2
- HCRTR2 | c.32del p.P11Lfs*11 | Frame Shift Del (DEL) | VAF 21/96 reads (22%) | catalogued as rs755844571, COSV63794110; called by mutect2, pindel, varscan2
- HECW1 | c.491A>G p.H164R | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs1490028785, COSV101224181; called by muse, mutect2, varscan2
- HECW1 | c.4618G>A p.V1540M | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs776126992, COSV101224182; called by muse, mutect2, varscan2
- HERC2 | c.7207C>T p.L2403F | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as rs1337132410, COSV99876199; called by muse, mutect2, varscan2
- HHIPL1 | c.1438G>A p.V480M | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100415322; called by muse, mutect2, varscan2
- HK1 | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1424205690, COSV53857434; called by muse, mutect2, varscan2
- HMX2 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV60593111; called by muse, mutect2, varscan2
- HOMEZ | c.1403G>T p.R468M | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.147); catalogued as rs1228899370, COSV100664177; called by muse, mutect2, varscan2
- HS3ST6 | c.640G>T p.G214C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV53535244, COSV99562843; called by muse, mutect2, varscan2
- HSD17B12 | c.392T>C p.V131A | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99550984; called by muse, mutect2, varscan2
- HSPA12A | c.1592G>A p.R531H | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201237054; called by muse, mutect2, varscan2
- HTR1B | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV64051824; called by muse, mutect2, varscan2
- IDE | c.1706del p.L569Cfs*45 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as rs771790236; called by mutect2, varscan2
- IFI16 | c.252del p.E85Kfs*3 | Frame Shift Del (DEL) | VAF 14/69 reads (20%) | catalogued as rs1557862995; called by mutect2, pindel, varscan2
- IFNA17 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.052); catalogued as COSV101303480; called by muse, mutect2, varscan2
- IFT88 | c.357C>T p.G119= (on ENST00000319980 / NM_001318493.2; = p.G110= on NM_006531.5 and 9 other RefSeq transcripts) | Splice Region (SNP) | VAF 18/50 reads (36%) | catalogued as COSV100179851; called by muse, mutect2, varscan2
- IGSF9B | c.3061T>C p.S1021P | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.54); catalogued as COSV100318249; called by muse, mutect2, varscan2
- IL17RA | c.2392T>C p.S798P | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766900912, COSV100083401; called by muse, varscan2
- IL17RD | c.1288G>A p.V430M | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV99577948; called by muse, mutect2, varscan2
- IL1R2 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs764905517, COSV60210305; called by muse, mutect2, varscan2
- IL2RA | c.582A>G p.P194= | Splice Region (SNP) | VAF 11/150 reads (7%) | catalogued as rs1164101257, COSV99906861; called by muse, mutect2
- IL2RG | c.1082dup p.C362Mfs*7 | Frame Shift Ins (INS) | VAF 6/12 reads (50%) | catalogued as rs745545309; called by mutect2, varscan2
- INCENP | c.407T>C p.M136T | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99611368; called by muse, mutect2, varscan2
- INHBA | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV54219500, COSV54222254; called by muse, mutect2, varscan2
- IQGAP3 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 21/222 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs190122865, COSV100752307; called by muse, mutect2
- IRF2 | c.150del p.D51Mfs*19 | Frame Shift Del (DEL) | VAF 24/79 reads (30%) | catalogued as COSV101165816; called by mutect2, pindel, varscan2
- ITFG2 | c.150T>A p.N50K | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99958297; called by muse, mutect2
- ITGA4 | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs762176587, COSV99276713; called by muse, mutect2, varscan2
- ITIH5 | c.1204G>A p.V402I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs768826767, COSV53662968; called by muse, mutect2
- JMJD7-PLA2G4B | c.2645T>A p.L882* | Nonsense Mutation (SNP) | VAF 27/70 reads (39%) | catalogued as COSV100312056; called by muse, mutect2, varscan2
- JPH3 | c.2221A>G p.I741V | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV99413871; called by muse, mutect2, varscan2
- KAT6B | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54742244; called by muse, mutect2, varscan2
- KAT6B | c.3718G>A p.E1240K | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.955); catalogued as rs140989004, COSV99056196; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCND3 | c.507G>A p.M169I | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100138234; called by muse, mutect2, varscan2
- KCNH5 | c.1426G>A p.A476T | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.039); catalogued as rs536465196, COSV100527762; called by muse, mutect2, varscan2
- KCNMA1 | c.358C>A p.H120N | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.096); catalogued as COSV99699194; called by muse, mutect2, varscan2
- KDM3A | c.2512+2T>C p.X838_splice | Splice Site (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100460841; called by muse, mutect2
- KIAA0895L | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as rs918764196, COSV99220596; called by muse, mutect2, varscan2
- KIAA1109 | c.6805A>G p.T2269A | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV99170099; called by muse, mutect2, varscan2
- KIAA2026 | c.1736T>A p.I579N | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as COSV101199182; called by muse, mutect2, varscan2
- KIFC3 | c.1957G>A p.V653M | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs201137413, COSV101109337; called by mutect2, varscan2
- KLC2 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as rs758112769, COSV57582469; called by muse, mutect2, varscan2
- KLF10 | c.911del p.P304Lfs*31 | Frame Shift Del (DEL) | VAF 13/50 reads (26%) | catalogued as rs771864173; called by mutect2, pindel, varscan2
- KLK14 | c.740C>T p.T247M | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs778298496, COSV50067907; called by muse, mutect2, varscan2
- LAMA1 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs761620468, COSV67533271; called by muse, mutect2, varscan2
- LAMB3 | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs753850608, COSV100620491; called by muse, mutect2, varscan2
- LFNG | c.736-1G>A p.X246_splice (on ENST00000222725 / NM_001040167.2; = p.X117_splice on NM_002304.2) | Splice Site (SNP) | VAF 9/46 reads (20%) | catalogued as COSV99761928; called by muse, mutect2, varscan2
- LIG3 | c.1457C>T p.A486V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1301120665, COSV99253021; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 18/47 reads (38%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LPAR1 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.144); catalogued as COSV100730991; called by muse, mutect2, varscan2
- LRFN1 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1322536543, COSV99953470; called by muse, mutect2
- LRP1B | c.10226G>A p.C3409Y | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99081263; called by muse, mutect2, varscan2
- LRRC36 | c.1636C>A p.L546I | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99339027; called by muse, mutect2, varscan2
- LRRC52 | c.99A>C p.Q33H | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV99674059; called by muse, mutect2, varscan2
- LRRC7 | c.880G>A p.E294K (on ENST00000651989 / NM_001370785.2; = p.E261K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.675); catalogued as COSV99229107; called by muse, mutect2, varscan2
- LRRN3 | c.1815dup p.C606Mfs*12 | Frame Shift Ins (INS) | VAF 10/52 reads (19%) | catalogued as rs747411092; called by mutect2, varscan2
- LSMEM2 | c.227T>C p.L76P | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV100269772; called by muse, mutect2, varscan2
- LSS | c.859A>G p.T287A | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.57); catalogued as rs1360366764, COSV100711019; called by muse, mutect2
- MACO1 | c.306del p.F102Lfs*47 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | catalogued as rs752439249; called by mutect2, varscan2
- MAN2C1 | c.2003T>C p.L668P | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99145742; called by muse, mutect2, varscan2
- MANBA | c.1369-1G>T p.X457_splice (on ENST00000642252; = p.X411_splice on NM_005908.4) | Splice Site (SNP) | VAF 16/28 reads (57%) | catalogued as COSV99899091; called by muse, mutect2, varscan2
- MAP3K11 | c.2399G>A p.R800Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as rs751204773, COSV100442337; called by muse, mutect2, varscan2
- MAP3K14 | c.1838C>T p.P613L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757794609, COSV100766551; called by muse, varscan2
- MATN4 | c.1409G>A p.R470Q (on ENST00000372754; = p.R429Q on NM_003833.4) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | PolyPhen possibly damaging (0.703); catalogued as COSV100637001, COSV100637137; called by muse, mutect2, varscan2
- MB21D2 | c.1371del p.K457Nfs*5 | Frame Shift Del (DEL) | VAF 22/126 reads (17%) | catalogued as rs34835215; called by mutect2, pindel, varscan2
- MBD3 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.926); catalogued as rs1156358847, COSV50084027; called by muse, mutect2, varscan2
- MBD6 | c.2240A>G p.D747G | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1263442767, COSV100851792; called by muse, mutect2, varscan2
- MEAK7 | c.1142G>A p.S381N | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100640433; called by muse, mutect2, varscan2
- MED23 | c.1988C>T p.P663L | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as rs372590711; called by muse, mutect2, varscan2
- MEGF9 | c.1648T>C p.F550L | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100879515; called by muse, mutect2, varscan2
- MEP1B | c.62T>C p.L21S | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV99329079; called by muse, mutect2
- MEX3A | c.1538C>T p.T513M | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101348962; called by muse, mutect2, varscan2
- MFSD2B | c.772G>T p.D258Y | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100601192; called by muse, mutect2
- MICOS13 | c.150del p.A51Pfs*39 | Frame Shift Del (DEL) | VAF 16/70 reads (23%) | catalogued as rs751944867; called by mutect2, pindel, varscan2
- MINAR1 | c.2512A>G p.N838D | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV100549157; called by muse, mutect2, varscan2
- MKI67 | c.5638A>G p.S1880G | Missense Mutation (SNP) | VAF 64/292 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as COSV100896903; called by muse, mutect2, varscan2
- MMP10 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs754542564, COSV99666736; called by muse, mutect2, varscan2
- MORC1 | c.701G>T p.R234M | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV51714138, COSV99227463; called by muse, mutect2, varscan2
- MPV17L2 | c.534G>T p.W178C | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99718086; called by muse, mutect2, varscan2
- MRAP | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV100353329; called by muse, mutect2, varscan2
- MTMR7 | c.1792G>A p.D598N | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as rs367618699; called by muse, mutect2
- MUC16 | c.2712G>A p.W904* | Nonsense Mutation (SNP) | VAF 18/39 reads (46%) | catalogued as rs1367727609, COSV101201097; called by muse, mutect2, varscan2
- MUC4 | c.14705del p.N4902Tfs*8 (on ENST00000463781 / NM_018406.7; = p.N666Tfs*8 on NM_004532.6) | Frame Shift Del (DEL) | VAF 20/98 reads (20%) | catalogued as rs766716021; called by mutect2, varscan2
- MXRA5 | c.6436G>A p.A2146T | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs773378476, COSV99478763; called by muse, varscan2
- MYBPC2 | c.2078T>C p.F693S | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.348); catalogued as COSV100731982; called by muse, mutect2, varscan2
- MYCBP2 | c.796A>G p.T266A (on ENST00000357337; = p.T304A on NM_015057.5) | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as COSV100631479; called by muse, mutect2, varscan2
- MYCL | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs768216635, COSV65693368; called by muse, mutect2, varscan2
- MYH6 | c.654G>T p.E218D | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV100676914, COSV62449089; called by muse, mutect2, varscan2
- MYL12B | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1487706235, COSV52899061; called by muse, mutect2, varscan2
- MYO10 | c.3674dup p.S1226Lfs*25 | Frame Shift Ins (INS) | VAF 24/96 reads (25%) | catalogued as rs760302326, COSV57018963; called by mutect2, varscan2
- MYO16 | c.2689G>T p.D897Y | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1469161717, COSV99194426; called by muse, mutect2
- MYO7B | c.2249A>G p.H750R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV101268358; called by muse, mutect2
- NAT16 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.81); PolyPhen benign (0.009); catalogued as rs373407624; called by muse, mutect2
- NCLN | c.326T>G p.V109G | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV99860091; called by muse, mutect2, varscan2
- NCSTN | c.1864C>T p.R622C | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1463308762, COSV99666957; called by muse, mutect2, varscan2
- NDST1 | c.1739C>T p.P580L | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99938950, COSV99939043; called by muse, mutect2
- NDST2 | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV100014296; called by muse, mutect2, varscan2
- NDUFV2 | c.65T>C p.V22A | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100571744; called by muse, mutect2, varscan2
- NES | c.3756G>T p.R1252S | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100957961; called by muse, mutect2, varscan2
- NINL | c.907G>A p.V303M | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1348498999, COSV54001513, COSV99625992; called by muse, mutect2, varscan2
- NIPBL | c.4238A>G p.Q1413R | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV99242199; called by muse, mutect2, varscan2
- NKX2-2 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763629654, COSV101010611; called by muse, mutect2, varscan2
- NOMO3 | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758324446; called by mutect2, varscan2
- NOP56 | c.1169C>T p.T390M | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1244539943, COSV100250292; called by muse, mutect2, varscan2
- NOTCH3 | c.5518G>A p.E1840K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54657801; called by muse, mutect2
- NPR3 | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.717); catalogued as COSV54086734, COSV54090126; called by muse, mutect2, varscan2
- NPY1R | c.362G>A p.C121Y | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99649011; called by muse, mutect2, varscan2
- NSD1 | c.2476A>G p.S826G | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as COSV100729723; called by muse, mutect2, varscan2
- NUDT11 | c.41A>G p.E14G | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as COSV101047103; called by muse, mutect2
- NUF2 | c.983A>G p.E328G | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV99616783; called by muse, mutect2, varscan2
- OGDH | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs200566080, COSV99758632; called by muse, mutect2, varscan2
- OLFML2A | c.1547G>A p.R516H | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as rs768248990, COSV99992820; called by muse, mutect2, varscan2
- OPTN | c.76del p.H26Tfs*19 | Frame Shift Del (DEL) | VAF 16/106 reads (15%) | catalogued as rs753966040; called by mutect2, pindel, varscan2
- OR4D11 | c.424A>G p.T142A | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs1432928710, COSV100506623; called by muse, mutect2, varscan2
- OR4E2 | c.455del p.G152Vfs*6 | Frame Shift Del (DEL) | VAF 23/128 reads (18%) | catalogued as rs764448584, COSV100330146; called by mutect2, pindel, varscan2
- OR4Q3 | c.560A>G p.Y187C | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100057296; called by muse, mutect2, varscan2
- OR52K1 | c.316C>A p.L106I | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (1); PolyPhen possibly damaging (0.585); catalogued as COSV100297719; called by muse, mutect2, varscan2
- OR5I1 | c.180del p.M61Cfs*11 | Frame Shift Del (DEL) | VAF 15/53 reads (28%) | catalogued as COSV56887887; called by mutect2, pindel, varscan2
- OR7E24 | c.504del p.F168Lfs*12 | Frame Shift Del (DEL) | VAF 16/76 reads (21%) | catalogued as rs1031417078; called by mutect2, pindel, varscan2
- OR8S1 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.546); catalogued as rs374454437; called by muse, mutect2, varscan2
- OSBPL3 | c.820A>G p.R274G | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs767181357, COSV100514447; called by muse, mutect2, varscan2
- OSCAR | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.246); catalogued as rs781434816, COSV99500059; called by muse, mutect2, varscan2
- OXCT1 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs755989003, COSV52166822; called by muse, mutect2, varscan2
- OXT | c.324C>T p.D108= | Splice Region (SNP) | VAF 9/77 reads (12%) | catalogued as rs753801172, COSV99459192; called by muse, mutect2
- P3H4 | c.746A>G p.H249R | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs1025922741, COSV100387976; called by muse, mutect2, varscan2
- PADI2 | c.499T>G p.C167G | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100971061; called by muse, mutect2, varscan2
- PARD3 | c.1586C>T p.S529L | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs1186195419, COSV60755276; called by muse, mutect2, varscan2
- PARD6B | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763915421, COSV100859931, COSV65404197; called by muse, mutect2, varscan2
- PARP14 | c.3965del p.N1322Ifs*26 | Frame Shift Del (DEL) | VAF 15/30 reads (50%) | catalogued as rs758945932; called by mutect2, varscan2
- PARP15 | c.1787C>T p.A596V (on ENST00000464300 / NM_001113523.3; = p.A362V on NM_152615.2) | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs528176249, COSV100117175; called by muse, mutect2, varscan2
- PASK | c.2431C>T p.R811* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as rs776234374, COSV52158022; called by muse, mutect2, varscan2
- PAX5 | c.253G>T p.G85* | Nonsense Mutation (SNP) | VAF 66/183 reads (36%) | catalogued as COSV100814524, COSV63913183; called by muse, mutect2, varscan2
- PAX5 | c.76dup p.V26Gfs*49 | Frame Shift Ins (INS) | VAF 18/86 reads (21%) | catalogued as rs767894241; called by mutect2, varscan2
- PCDHA13 | c.1937G>A p.R646H | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.056); catalogued as COSV56521480, COSV56527393; called by muse, mutect2, varscan2
- PDZD2 | c.7147G>T p.G2383C | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV56859815; called by muse, mutect2, varscan2
- PEG3 | c.1896_1897del p.C632Wfs*7 | Frame Shift Del (DEL) | VAF 12/71 reads (17%) | catalogued as COSV55639086; called by pindel, varscan2
- PEG3 | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99690077; called by muse, mutect2, varscan2
- PELI3 | c.1207G>A p.G403S | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.547); catalogued as rs749940073, COSV100291882; called by muse, mutect2, varscan2
- PGBD4 | c.1487del p.K496Sfs*109 | Frame Shift Del (DEL) | VAF 9/44 reads (20%) | catalogued as rs1454502156; called by mutect2, pindel, varscan2
- PGC | c.779G>A p.G260D | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as COSV100026410; called by muse, mutect2
- PHLDB1 | c.3967T>G p.F1323V | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV99874758; called by muse, mutect2, varscan2
- PHYHIPL | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.857); catalogued as rs1473951149, COSV100874227; called by muse, mutect2, varscan2
- PIGZ | c.1467dup p.T490Dfs*2 | Frame Shift Ins (INS) | VAF 11/49 reads (22%) | catalogued as rs759867499; called by mutect2, varscan2
- PIK3C2A | c.3077G>A p.R1026Q | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as rs756345749, COSV56404893; called by muse, mutect2, varscan2
- PKD2L1 | c.764del p.G255Afs*64 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | catalogued as rs1169311338; called by mutect2, pindel, varscan2
- PKDCC | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs755188085, COSV54307451; called by muse, mutect2, varscan2
- PKHD1 | c.10922T>C p.M3641T | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.346); catalogued as COSV100945126; called by muse, mutect2, varscan2
- PKLR | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 41/176 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as COSV100713000; called by muse, mutect2, varscan2
- PLAAT4 | c.483del p.A162Rfs*56 | Frame Shift Del (DEL) | VAF 40/128 reads (31%) | catalogued as rs745860467; called by mutect2, varscan2
- PLCE1 | c.3527T>G p.L1176R | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.099); catalogued as COSV99596696; called by muse, mutect2, varscan2
- PLEKHH2 | c.2277A>C p.R759S | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.281); catalogued as COSV99175021; called by muse, mutect2, varscan2
- PLPPR2 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as rs1452472654, COSV52260516; called by muse, mutect2, varscan2
- PLXNA3 | c.49del p.A17Pfs*12 | Frame Shift Del (DEL) | VAF 15/24 reads (63%) | catalogued as rs782247826; called by mutect2, varscan2
- PLXNA4 | c.5200G>A p.V1734I | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs1345661289, COSV100326403; called by muse, mutect2, varscan2
- PMEPA1 | c.624del p.S209Afs*61 | Frame Shift Del (DEL) | VAF 11/61 reads (18%) | catalogued as rs751873496; called by mutect2, pindel, varscan2
- PMPCA | c.1110-2A>G p.X370_splice | Splice Site (SNP) | VAF 13/34 reads (38%) | catalogued as COSV100867829; called by muse, mutect2, varscan2
- PODXL | c.359T>A p.I120N | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100539723; called by muse, mutect2, varscan2
- POLG | c.1098dup p.P367Afs*21 | Frame Shift Ins (INS) | VAF 30/108 reads (28%) | catalogued as rs750787511; called by mutect2, pindel, varscan2
- POLRMT | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs1479179924, COSV101648686; called by muse, mutect2, varscan2
- POM121L12 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV68692951, COSV68693360; called by muse, mutect2, varscan2
- POP1 | c.2330G>A p.C777Y | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.321); catalogued as COSV100856058; called by muse, mutect2, varscan2
- POT1 | c.1594+2T>A p.X532_splice | Splice Site (SNP) | VAF 9/70 reads (13%) | catalogued as COSV100714127; called by muse, mutect2, varscan2
- PPARA | c.507C>T p.N169= | Splice Region (SNP) | VAF 34/120 reads (28%) | catalogued as rs146427416; called by muse, mutect2, varscan2
- PPFIBP2 | c.1148A>G p.K383R | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.209); catalogued as rs959214027, COSV100206864; called by muse, varscan2
- PPIG | c.2042del p.K681Rfs*12 | Frame Shift Del (DEL) | VAF 19/75 reads (25%) | catalogued as rs775130624; called by mutect2, varscan2
- PPP1R18 | c.128T>C p.L43P | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99223867; called by muse, mutect2, varscan2
- PPP2R5C | c.254A>G p.N85S | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as COSV100159875; called by muse, mutect2, varscan2
- PPRC1 | c.2819del p.P940Hfs*6 | Frame Shift Del (DEL) | VAF 16/51 reads (31%) | catalogued as rs768056539; called by mutect2, varscan2
- PREB | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as COSV53206919; called by muse, mutect2, varscan2
- PRF1 | c.1428del p.L478* | Frame Shift Del (DEL) | VAF 10/94 reads (11%) | catalogued as rs748926167, CD132539, COSV100942602; called by mutect2, pindel, varscan2
- PRKAR1B | c.260dup p.N88Efs*56 | Frame Shift Ins (INS) | VAF 14/80 reads (18%) | catalogued as rs764069617; called by mutect2, varscan2
- PRPH2 | c.145A>G p.S49G | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.885); catalogued as COSV100028220; called by muse, mutect2, varscan2
- PRR11 | c.66del p.E23Kfs*9 | Frame Shift Del (DEL) | VAF 29/75 reads (39%) | catalogued as rs753236928; called by mutect2, varscan2
- PSCA | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.078); catalogued as rs1554638441, COSV100008157; called by muse, mutect2, varscan2
- PSME4 | c.5413del p.T1805Pfs*69 | Frame Shift Del (DEL) | VAF 22/117 reads (19%) | catalogued as COSV101122574; called by mutect2, varscan2
- PTPN21 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373299637, COSV60848892; called by muse, mutect2, varscan2
- PTPRA | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV53783958; called by muse, mutect2, varscan2
- PTPRN2 | c.1493G>A p.G498D | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.093); catalogued as COSV101235231; called by muse, mutect2, varscan2
- PXK | c.616-1G>A p.X206_splice | Splice Site (SNP) | VAF 13/66 reads (20%) | catalogued as COSV100244380, COSV57095425; called by muse, mutect2, varscan2
- R3HCC1L | c.1105G>T p.G369C | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as COSV100107502; called by muse, mutect2, varscan2
- RAB40AL | c.774G>T p.K258N | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.355); catalogued as COSV99505240; called by muse, mutect2, varscan2
- RAD51AP2 | c.357del p.S120Hfs*8 | Frame Shift Del (DEL) | VAF 41/119 reads (34%) | catalogued as rs750569378, COSV67588127; called by mutect2, pindel, varscan2
- RAD54L2 | c.1796G>A p.R599Q | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.357); catalogued as rs367686213; called by muse, mutect2, varscan2
- RAG2 | c.1496del p.K499Sfs*4 | Frame Shift Del (DEL) | VAF 21/61 reads (34%) | catalogued as rs1251406873; called by mutect2, pindel, varscan2
- RAI1 | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99884814; called by muse, mutect2, varscan2
- RASGRF1 | c.2050G>A p.A684T | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs779403459, COSV101174715; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 23/86 reads (27%) | catalogued as rs762006287; called by mutect2, varscan2
- RBM6 | c.2000C>T p.T667I | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99805804; called by muse, mutect2, varscan2
- REG1B | c.20T>C p.F7S | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100521489; called by muse, mutect2, varscan2
- RERE | c.3727C>T p.P1243S | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.988); catalogued as rs749567752, COSV100557137, COSV100557392; called by muse, mutect2, varscan2
- RET | c.1343A>G p.N448S | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.11); catalogued as rs760832715, COSV100394147; called by muse, mutect2, varscan2
- RETREG1 | c.950G>T p.G317V (on ENST00000306320 / NM_001034850.2; = p.G176V on NM_019000.4) | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100104809; called by muse, mutect2
- RFPL2 | c.731A>G p.E244G | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99964514; called by muse, mutect2, varscan2
- RHBDD2 | c.289G>A p.V97I | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as rs782471564, COSV99138517; called by muse, mutect2, varscan2
- RNASEH2A | c.488C>T p.T163M | Missense Mutation (SNP) | VAF 66/128 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1046057251, COSV99677388; called by muse, varscan2
- RNF207 | c.1451C>G p.S484C | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV100933757, COSV65008443; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 18/92 reads (20%) | catalogued as rs755128667, COSV68457540; called by mutect2, varscan2
- ROBO2 | c.1007A>G p.E336G | Missense Mutation (SNP) | VAF 55/197 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.105); catalogued as COSV100169264, COSV100170755; called by muse, mutect2, varscan2
- ROCK1 | c.3921del p.K1307Nfs*3 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs752898741; called by mutect2, varscan2
- RPH3AL | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as rs765673764, COSV58745474; called by muse, mutect2, varscan2
- RPL32 | c.99T>C p.R33= | Splice Region (SNP) | VAF 62/258 reads (24%) | catalogued as COSV99832832; called by muse, mutect2, varscan2
- RPTN | c.2127G>T p.Q709H | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.656); catalogued as COSV100285687; called by muse, mutect2, varscan2
- RSC1A1 | c.1057A>G p.T353A | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV100197856; called by muse, mutect2, varscan2
- RYR1 | c.13643A>G p.Q4548R | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.446); catalogued as rs1464899615, COSV100616696; called by muse, mutect2, varscan2
- RYR3 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 17/25 reads (68%) | catalogued as rs769820824, COSV101212023, COSV66811477; called by muse, mutect2, varscan2
- S100A5 | c.96G>T p.K32N | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.465); catalogued as COSV100573141; called by muse, mutect2, varscan2
- SBF2 | c.3558G>T p.K1186N | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV99815442; called by muse, varscan2
- SCGN | c.400C>A p.L134I | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.347); catalogued as COSV100618833; called by muse, mutect2, varscan2
- SCRIB | c.1130T>C p.L377P | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100253985; called by muse, mutect2, varscan2
- SCTR | c.746_748del p.F249del | In Frame Del (DEL) | VAF 20/67 reads (30%) | catalogued as rs1416056477; called by pindel, varscan2
- SDK2 | c.6294G>T p.Q2098H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV101168352; called by muse, mutect2, varscan2
- SECTM1 | c.704T>C p.L235P | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.354); catalogued as COSV99486354; called by muse, mutect2, varscan2
- SEMA3E | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as rs765052488, COSV100319392; called by muse, mutect2, varscan2
- SEMA4A | c.182T>A p.L61H | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100740704; called by muse, mutect2, varscan2
- SEMA5B | c.3119C>T p.T1040M | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs756314106, COSV99532954; called by muse, mutect2, varscan2
- SERBP1 | c.700T>C p.S234P | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.151); catalogued as COSV100769158; called by muse, mutect2, varscan2
- SF3A2 | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 16/77 reads (21%) | catalogued as COSV99678060; called by muse, mutect2, varscan2
- SFRP5 | c.920A>G p.Y307C | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV99823256; called by muse, mutect2, varscan2
- SHC1 | c.1087del p.V363Wfs*2 (on ENST00000368445 / NM_183001.5; = p.V253Wfs*2 on NM_003029.5) | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs746556543; called by mutect2, varscan2
- SHC3 | c.1766C>T p.P589L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.485); catalogued as COSV101012425; called by muse, mutect2, varscan2
- SHF | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs750043642, COSV52049875; called by muse, mutect2, varscan2
- SHH | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99793514; called by muse, mutect2, varscan2
- SHLD2 | c.1675G>C p.A559P | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV100079437; called by muse, mutect2, varscan2
- SIAH3 | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.271); catalogued as rs780788402, COSV68552195; called by muse, mutect2, varscan2
- SINHCAF | c.218del p.N73Tfs*6 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs771414532; called by mutect2, varscan2
- SLC23A2 | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100595210; called by muse, mutect2
- SLC25A13 | c.1474C>T p.R492W | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs763272772, COSV55711834; called by muse, mutect2, varscan2
- SLC25A45 | c.251T>C p.L84P | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771942747, COSV99587401; called by muse, mutect2, varscan2
- SLC2A13 | c.647T>C p.I216T | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55122890; called by muse, mutect2, varscan2
- SLC34A3 | c.1210G>T p.G404W | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100746709; called by muse, mutect2, varscan2
- SLC38A10 | c.1309G>A p.V437M | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs762574221, COSV99917815; called by muse, mutect2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC4A3 | c.3108del p.L1037Sfs*24 | Frame Shift Del (DEL) | VAF 14/63 reads (22%) | catalogued as rs757961785; called by mutect2, pindel, varscan2
- SLC5A5 | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as rs1304927206, COSV99715312; called by muse, mutect2, varscan2
- SLC5A6 | c.1738C>T p.R580W | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.859); catalogued as rs573985573, COSV100143240; called by muse, mutect2, varscan2
- SLC6A15 | c.341T>C p.L114P | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs772380561, COSV57020162, COSV57026317; called by muse, mutect2, varscan2
- SLC9A5 | c.1928G>A p.R643Q | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.397); catalogued as rs769149966, COSV55361671; called by muse, mutect2, varscan2
- SMARCA2 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs868703938, COSV100571449; called by muse, varscan2
- SMARCD2 | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753722687, COSV56738573; called by muse, mutect2, varscan2
- SMG1 | c.10456G>A p.V3486I | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs759196617, COSV101246696; called by muse, mutect2, varscan2
- SNPH | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as rs138783054; called by muse, mutect2, varscan2
- SNRPN | c.597G>T p.M199I | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV100578510; called by muse, mutect2, varscan2
- SNTB1 | c.593C>T p.T198M | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs1239910440, COSV101180088; called by muse, mutect2, varscan2
- SNX13 | c.314A>G p.Q105R | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.113); catalogued as COSV101285175; called by muse, mutect2, varscan2
- SORBS1 | c.3527G>A p.R1176Q | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as rs765283931, COSV53355552; called by muse, mutect2, varscan2
- SPDYC | c.369G>T p.E123D | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101017274; called by muse, mutect2, varscan2
- SPEN | c.3053del p.K1018Sfs*13 | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | catalogued as rs1557758720; called by mutect2, pindel, varscan2
- SPG11 | c.5650C>T p.R1884C | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs752889027, COSV55999142; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPG7 | c.1604C>T p.T535I (on ENST00000268704; = p.T542I on NM_003119.4) | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.112); catalogued as COSV99245344; called by muse, mutect2, varscan2
- SPRED3 | c.296C>G p.A99G | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV100612814; called by muse, mutect2, varscan2
- SPTAN1 | c.7207G>A p.V2403I | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.77); PolyPhen benign (0.146); catalogued as rs1057520841, COSV100823745; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SPTB | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775276485, COSV67629928; called by muse, mutect2
- SRL | c.961G>C p.V321L | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.64); catalogued as COSV101281367, COSV68423607; called by muse, mutect2, varscan2
- SRRT | c.1705G>A p.V569I | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.163); catalogued as COSV99574474; called by muse, mutect2, varscan2
- SS18 | c.139T>C p.C47R | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99294381; called by muse, mutect2, varscan2
- STAT5B | c.394A>G p.S132G | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99511259; called by muse, mutect2, varscan2
- STRIP1 | c.2138T>C p.V713A | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.627); catalogued as COSV100874107; called by muse, mutect2, varscan2
- STXBP5L | c.1834G>C p.V612L | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99875910; called by muse, mutect2, varscan2
- SUFU | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201326378, COSV64016546; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SWAP70 | c.305del p.N102Tfs*31 | Frame Shift Del (DEL) | VAF 20/73 reads (27%) | catalogued as rs749995893; called by mutect2, varscan2
- SYCP2L | c.2035A>G p.T679A | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV99305694; called by muse, mutect2, varscan2
- SYNGAP1 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 66/111 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1264547497, COSV99538004; called by muse, mutect2, varscan2
- TAS2R42 | c.745del p.S249Pfs*18 | Frame Shift Del (DEL) | VAF 14/73 reads (19%) | catalogued as rs753101364; called by mutect2, varscan2
- TBCK | c.2330C>T p.T777I (on ENST00000273980 / NM_001163436.4; = p.T714I on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV99913024; called by muse, mutect2, varscan2
- TDRD3 | c.1430T>C p.V477A | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV52154622; called by muse, mutect2, varscan2
- TENM4 | c.6662G>T p.G2221V | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV53650364, COSV99577940; called by muse, mutect2, varscan2
- TENT4B | c.1864C>T p.R622* (on ENST00000561678 / NM_001365323.2; = p.R607* on NM_001040284.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 17/57 reads (30%) | catalogued as COSV100665815; called by muse, mutect2, varscan2
- TEP1 | c.5566del p.V1856Lfs*45 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as rs746695887; called by mutect2, pindel, varscan2
- TET2 | c.2803G>T p.G935* | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | catalogued as COSV54395139; called by muse, mutect2, varscan2
- TFAP4 | c.90C>T p.S30= | Splice Region (SNP) | VAF 9/72 reads (13%) | catalogued as COSV99200094; called by muse, mutect2, varscan2
- TFEB | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57823456; called by muse, mutect2, varscan2
- THADA | c.3479G>A p.R1160H | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100369330; called by muse, mutect2, varscan2
- THSD7B | c.923G>A p.R308K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs759237070, COSV55695459; called by muse, mutect2, varscan2
- TICAM1 | c.1925del p.P642Hfs*50 | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | catalogued as COSV50235787; called by mutect2, varscan2
- TJP1 | c.3631G>T p.A1211S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.031); catalogued as COSV100633048; called by muse, mutect2, varscan2
- TLR5 | c.590C>T p.T197M | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as rs146146738; called by muse, mutect2, varscan2
- TMEM225 | c.352A>G p.I118V | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100902870; called by muse, mutect2, varscan2
- TMEM60 | c.231del p.A78Pfs*11 | Frame Shift Del (DEL) | VAF 24/109 reads (22%) | catalogued as rs749773249; called by mutect2, varscan2
- TMPRSS6 | c.631+2T>C p.X211_splice | Splice Site (SNP) | VAF 17/53 reads (32%) | catalogued as COSV60979596; called by muse, varscan2
- TNK2 | c.2840G>A p.G947D | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs930623998, COSV100361095; called by muse, mutect2
- TNRC18 | c.8464G>A p.G2822R | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1342472551, COSV100078942, COSV60307185; called by muse, mutect2, varscan2
- TOP3B | c.1891A>G p.M631V | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV64118686; called by muse, mutect2
- TRANK1 | c.3399A>T p.E1133D | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV100084429; called by muse, varscan2
- TRIM29 | c.577T>C p.S193P | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100531958; called by muse, mutect2, varscan2
- TRIP11 | c.2123del p.N708Tfs*7 | Frame Shift Del (DEL) | VAF 37/128 reads (29%) | catalogued as rs747106242; called by mutect2, pindel, varscan2
- TRMT1 | c.1790G>A p.R597Q | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1480940706, COSV99317169; called by muse, mutect2, varscan2
- TRNT1 | c.214G>T p.G72* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV99285890; called by muse, mutect2, varscan2
- TRPV4 | c.455C>A p.P152H | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99924992; called by muse, mutect2, varscan2
- TRRAP | c.5701G>A p.V1901I (on ENST00000359863 / NM_001244580.1; = p.V1883I on NM_003496.3) | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as COSV100721744; called by muse, mutect2
- TSC2 | c.740T>C p.I247T | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV99555090; called by muse, mutect2, varscan2
- TSPYL6 | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.248); catalogued as COSV57816559; called by muse, mutect2, varscan2
- TTC23L | c.1041del p.E347Dfs*40 | Frame Shift Del (DEL) | VAF 10/47 reads (21%) | catalogued as rs942739160; called by mutect2, pindel, varscan2
- TTC3 | c.2334del p.E779Kfs*5 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | catalogued as rs756650873; called by mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 18/83 reads (22%) | catalogued as rs763254614; called by mutect2, varscan2
- TTN | c.38216G>A p.C12739Y (on ENST00000591111; = p.C5315Y on NM_003319.4) | Missense Mutation (SNP) | VAF 23/82 reads (28%) | PolyPhen probably damaging (0.998); catalogued as COSV100625969; called by muse, mutect2, varscan2
- TUBB6 | c.701G>C p.S234T | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.469); catalogued as COSV99302109; called by muse, mutect2, varscan2
- TUBGCP5 | c.2818C>T p.R940W | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759151472; called by muse, mutect2, varscan2
- TUBGCP6 | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs758447540, COSV50594436; called by muse, mutect2, varscan2
- TXNRD1 | c.1054G>A p.A352T (on ENST00000525566 / NM_001093771.3; = p.A254T on NM_003330.4) | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs911137254, COSV100723450; called by muse, varscan2
- TYRO3 | c.2352G>T p.M784I | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.268); catalogued as COSV99778015; called by muse, mutect2, varscan2
- U2SURP | c.1952T>C p.M651T | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as COSV67533758; called by muse, mutect2, varscan2
- UBE2E2 | c.364A>G p.T122A | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.338); catalogued as COSV100233603; called by muse, mutect2, varscan2
- UBE2O | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); catalogued as rs866617681, COSV100084923; called by muse, mutect2, varscan2
- UBN1 | c.2872del p.M958Cfs*7 | Frame Shift Del (DEL) | VAF 9/47 reads (19%) | catalogued as COSV99277799; called by mutect2, pindel, varscan2
- UBTD1 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752369963, COSV53968148; called by muse, mutect2, varscan2
- UIMC1 | c.895C>A p.Q299K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101022205; called by muse, mutect2, varscan2
- UNC79 | c.5836C>G p.Q1946E (on ENST00000393151 / NM_001346218.2; = p.Q1769E on NM_020818.5) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs376392862; called by muse, mutect2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | catalogued as rs767420916; called by mutect2, varscan2
- UQCRC1 | c.1330A>C p.I444L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV99179012; called by muse, mutect2, varscan2
- UROC1 | c.1558G>A p.V520M | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.228); catalogued as rs374247096; called by mutect2, varscan2
- USF3 | c.1469C>A p.P490Q | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.522); catalogued as COSV100324984; called by muse, mutect2, varscan2
- USP19 | c.1829A>C p.K610T | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100026433; called by muse, mutect2, varscan2
- USP26 | c.365C>T p.T122I | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as COSV63708641; called by muse, mutect2, varscan2
- USP44 | c.235del p.C79Vfs*9 | Frame Shift Del (DEL) | VAF 7/49 reads (14%) | catalogued as rs1322757046; called by mutect2, pindel, varscan2
- USP8 | c.1873G>A p.D625N | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.153); catalogued as rs768514589, COSV100209223; called by muse, mutect2, varscan2
- VPS13C | c.3220G>A p.V1074I (on ENST00000644861 / NM_020821.3; = p.V1031I on NM_017684.5) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV99829822; called by muse, mutect2, varscan2
- VPS39 | c.328A>G p.T110A (on ENST00000348544 / NM_001301138.2; = p.T99A on NM_015289.5) | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as COSV100529480; called by muse, mutect2, varscan2
- VSTM2A | c.205C>G p.P69A | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV100173475, COSV56495692; called by muse, mutect2, varscan2
- VWCE | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs926949322, COSV100076092; called by muse, mutect2, varscan2
- WASF3 | c.920del p.P307Rfs*28 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | catalogued as rs756173793; called by mutect2, varscan2
- WASHC2A | c.3298G>A p.A1100T | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as rs1358423847; called by muse, mutect2, varscan2
- WDFY3 | c.4762C>T p.Q1588* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as COSV99885143; called by muse, mutect2
- WDR25 | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs149345727; called by muse, mutect2, varscan2
- WFDC5 | c.16C>A p.L6I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.196); catalogued as COSV100332187; called by muse, mutect2
- WNK4 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.829); catalogued as rs1333933200, COSV99519548; called by muse, mutect2, varscan2
- WNK4 | c.1822del p.V608Cfs*53 | Frame Shift Del (DEL) | VAF 13/58 reads (22%) | catalogued as rs762079039; called by mutect2, pindel, varscan2
- WSB1 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); catalogued as COSV52216872; called by muse, mutect2
- WWC1 | c.1976C>T p.A659V | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs374770777; called by muse, mutect2, varscan2
- WWC1 | c.2695T>C p.S899P | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.811); catalogued as COSV99515724; called by muse, mutect2, varscan2
- XIRP2 | c.1537del p.D513Mfs*5 (on ENST00000628543; = p.D688Mfs*5 on NM_152381.6) | Frame Shift Del (DEL) | VAF 18/71 reads (25%) | catalogued as rs745648385; called by mutect2, pindel, varscan2
- XKR3 | c.304dup p.W102Lfs*17 | Frame Shift Ins (INS) | VAF 19/57 reads (33%) | catalogued as rs1370053077; called by mutect2, pindel, varscan2
- XRCC2 | c.801del p.K267Nfs*30 | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | catalogued as rs759063323; called by mutect2, pindel, varscan2
- ZBTB20 | c.320C>T p.T107M (on ENST00000474710 / NM_001164342.2; = p.T34M on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61846206; called by muse, mutect2, varscan2
- ZDHHC14 | c.345C>A p.S115R | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.63); catalogued as COSV100702387; called by muse, mutect2, varscan2
- ZNF138 | c.562del p.I188Ffs*56 (on ENST00000307355 / NM_001367572.1; = p.I162Ffs*56 on NM_006524.4) | Frame Shift Del (DEL) | VAF 12/85 reads (14%) | catalogued as rs750123890; called by mutect2, pindel, varscan2
- ZNF205 | c.211T>C p.W71R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs1555447736, COSV99530588; called by muse, mutect2, varscan2
- ZNF513 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52010033; called by muse, mutect2, varscan2
- ZNF518A | c.2785del p.T929Lfs*2 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | catalogued as rs781933025; called by mutect2, varscan2
- ZNF540 | c.994T>C p.C332R | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774109236, COSV100329858; called by muse, mutect2, varscan2
- ZNF583 | c.1481G>A p.C494Y | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52403640, COSV99382269; called by muse, mutect2, varscan2
- ZNF585B | c.731G>T p.C244F | Missense Mutation (SNP) | VAF 73/145 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs746293517, COSV100459600; called by muse, mutect2, varscan2
- ZNF592 | c.2324T>C p.V775A | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100246072; called by muse, mutect2, varscan2
- ZNF644 | c.1783A>G p.T595A | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV100494680; called by muse, mutect2, varscan2
- ZNF701 | c.894del p.K298Nfs*4 (on ENST00000301093; = p.K232Nfs*4 on NM_018260.3) | Frame Shift Del (DEL) | VAF 22/78 reads (28%) | catalogued as rs762217868; called by mutect2, pindel, varscan2
- ZNF750 | c.628G>A p.G210S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.224); catalogued as rs371325073, COSV99489490; called by muse, mutect2, varscan2
- ZNF99 | c.1920G>C p.E640D | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.218); catalogued as COSV101233921, COSV68054665; called by muse, varscan2
- ABR | c.205del p.D69Mfs*23 | Frame Shift Del (DEL) | VAF 15/66 reads (23%) | called by mutect2, pindel, varscan2
- ADAMTS9 | c.1865del p.N622Mfs*7 | Frame Shift Del (DEL) | VAF 15/60 reads (25%) | called by mutect2, pindel, varscan2
- AGO4 | c.1781del p.P594Qfs*51 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | called by mutect2, pindel, varscan2
- AHNAK | c.14956del p.S4986Afs*20 | Frame Shift Del (DEL) | VAF 21/98 reads (21%) | called by mutect2, pindel, varscan2
- ANKRD16 | c.457del p.L153Sfs*57 | Frame Shift Del (DEL) | VAF 13/61 reads (21%) | called by mutect2, pindel, varscan2
- ANKRD17 | c.6545del p.P2182Lfs*43 | Frame Shift Del (DEL) | VAF 21/137 reads (15%) | called by mutect2, pindel, varscan2
- APBB3 | c.64dup p.D22Gfs*32 | Frame Shift Ins (INS) | VAF 5/25 reads (20%) | called by mutect2, pindel, varscan2
- ARID1A | c.4563del p.A1522Pfs*5 | Frame Shift Del (DEL) | VAF 16/71 reads (23%) | called by mutect2, pindel, varscan2
- ASB14 | c.1551del p.K517Nfs*12 | Frame Shift Del (DEL) | VAF 23/101 reads (23%) | called by mutect2, pindel, varscan2
- ATXN2L | c.701del p.G234Vfs*33 | Frame Shift Del (DEL) | VAF 15/42 reads (36%) | called by mutect2, pindel, varscan2
- BCL2L15 | c.221del p.N74Tfs*33 | Frame Shift Del (DEL) | VAF 11/67 reads (16%) | called by mutect2, pindel, varscan2
- BLK | c.712del p.R238Gfs*27 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | called by mutect2, pindel, varscan2
- BOC | c.2065del p.E689Rfs*116 | Frame Shift Del (DEL) | VAF 23/104 reads (22%) | called by mutect2, pindel, varscan2
- BPGM | c.777del p.K259Nfs*24 | Frame Shift Del (DEL) | VAF 10/63 reads (16%) | called by mutect2, pindel, varscan2
- C5orf34 | c.1864dup p.T622Nfs*3 | Frame Shift Ins (INS) | VAF 12/68 reads (18%) | called by mutect2, varscan2
- CAB39L | c.624+1_624+2del p.X208_splice | Splice Site (DEL) | VAF 13/33 reads (39%) | called by mutect2, pindel, varscan2
- CASD1 | c.2347del p.C783Vfs*21 | Frame Shift Del (DEL) | VAF 20/100 reads (20%) | called by mutect2, pindel, varscan2
- CASZ1 | c.232del p.R78Afs*10 | Frame Shift Del (DEL) | VAF 18/55 reads (33%) | called by mutect2, pindel, varscan2
- CCDC141 | c.2860del p.M954Cfs*4 | Frame Shift Del (DEL) | VAF 33/107 reads (31%) | called by mutect2, pindel, varscan2
- CIC | c.346del p.V116Wfs*89 | Frame Shift Del (DEL) | VAF 18/55 reads (33%) | called by mutect2, pindel, varscan2
- CNTRL | c.3897del p.N1300Tfs*22 | Frame Shift Del (DEL) | VAF 19/56 reads (34%) | called by mutect2, pindel, varscan2
- COL11A1 | c.4660del p.T1554Rfs*33 | Frame Shift Del (DEL) | VAF 18/73 reads (25%) | called by mutect2, varscan2
- CRB1 | c.1154G>A p.C385Y | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CTBP2 | c.103del p.L35Wfs*17 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | called by mutect2, pindel, varscan2
- CTPS2 | c.1185del p.L396Wfs*9 | Frame Shift Del (DEL) | VAF 50/99 reads (51%) | called by mutect2, pindel, varscan2
- CTSC | c.315del p.F105Lfs*10 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | called by mutect2, pindel, varscan2
- CWF19L2 | c.1398del p.E467Nfs*22 | Frame Shift Del (DEL) | VAF 33/123 reads (27%) | called by mutect2, pindel, varscan2
- CYFIP1 | c.1029C>A p.Y343* | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2
- DHX16 | c.3097del p.I1033* | Frame Shift Del (DEL) | VAF 19/92 reads (21%) | called by mutect2, pindel, varscan2
- DNAH11 | c.2619del p.K873Nfs*4 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | called by mutect2, pindel, varscan2
- DOCK8 | c.6194T>G p.I2065S | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ECM2 | c.1130del p.N377Ifs*8 | Frame Shift Del (DEL) | VAF 15/53 reads (28%) | called by mutect2, pindel, varscan2
- EIF2AK4 | c.574del p.R192Gfs*43 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel
- EIF3J | c.180del p.E61Rfs*5 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | called by mutect2, varscan2
- ELOVL1 | c.466del p.V156* | Frame Shift Del (DEL) | VAF 15/77 reads (19%) | called by mutect2, pindel, varscan2
- ESYT3 | c.2624+2dup p.X875_splice | Splice Site (INS) | VAF 21/92 reads (23%) | called by mutect2, pindel, varscan2
- FCGBP | c.1766A>G p.Y589C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXM1 | c.1794del p.F598Lfs*35 | Frame Shift Del (DEL) | VAF 20/78 reads (26%) | called by mutect2, pindel, varscan2
- GFRA2 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GRIN1 | c.2596_2599del p.K866Vfs*188 | Frame Shift Del (DEL) | VAF 25/105 reads (24%) | called by mutect2, pindel, varscan2
- HNF1B | c.1560_1561dup p.Q521Pfs*71 | Frame Shift Ins (INS) | VAF 8/29 reads (28%) | called by mutect2, varscan2
- HSPA14 | c.1513_1514del p.I505* | Frame Shift Del (DEL) | VAF 9/59 reads (15%) | called by mutect2, pindel, varscan2
- ICE1 | c.4773del p.A1592Lfs*14 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | called by mutect2, pindel, varscan2
- ICE2 | c.59del p.N20Mfs*21 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- ITIH5 | c.1476dup p.S493Qfs*44 | Frame Shift Ins (INS) | VAF 15/74 reads (20%) | called by mutect2, pindel, varscan2
- JARID2 | c.1272del p.R425Gfs*36 | Frame Shift Del (DEL) | VAF 7/38 reads (18%) | called by mutect2, pindel, varscan2
- KCTD3 | c.133del p.S45Pfs*4 | Frame Shift Del (DEL) | VAF 34/126 reads (27%) | called by mutect2, varscan2
- KDM2B | c.44del p.P15Hfs*92 | Frame Shift Del (DEL) | VAF 26/97 reads (27%) | called by mutect2, pindel, varscan2
- KIAA0232 | c.3543dup p.S1182Ifs*33 | Frame Shift Ins (INS) | VAF 11/38 reads (29%) | called by mutect2, varscan2
- KMT2D | c.7416_7417dup p.Q2473Pfs*13 | Frame Shift Ins (INS) | VAF 5/51 reads (10%) | called by pindel, varscan2*
- KMT2D | c.7410_7411dup p.R2471Pfs*15 | Frame Shift Ins (INS) | VAF 5/52 reads (10%) | called by pindel, varscan2*
- KMT2E | c.942del p.E315Rfs*2 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel, varscan2
- KRT19 | c.1126_1128del p.E376del | In Frame Del (DEL) | VAF 10/37 reads (27%) | called by mutect2, pindel, varscan2
- LCOR | c.2574del p.E859Kfs*54 | Frame Shift Del (DEL) | VAF 19/81 reads (23%) | called by mutect2, pindel, varscan2
- LRFN5 | c.1574del p.L525Wfs*5 | Frame Shift Del (DEL) | VAF 46/172 reads (27%) | called by mutect2, pindel, varscan2
- M6PR | c.778del p.D260Mfs*63 | Frame Shift Del (DEL) | VAF 13/68 reads (19%) | called by pindel, varscan2
- MAPRE3 | c.543del p.C182Afs*31 | Frame Shift Del (DEL) | VAF 23/72 reads (32%) | called by mutect2, varscan2
- MGA | c.6240del p.V2081Wfs*21 (on ENST00000219905 / NM_001164273.1; = p.V1872Wfs*21 on NM_001080541.2) | Frame Shift Del (DEL) | VAF 10/49 reads (20%) | called by mutect2, pindel, varscan2
- MORC1 | c.179del p.G60Dfs*13 | Frame Shift Del (DEL) | VAF 17/123 reads (14%) | called by mutect2, pindel, varscan2
- MYO15A | c.3949_3950del p.S1317Rfs*6 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | called by pindel, varscan2
- MYO6 | c.171del p.D58Mfs*8 | Frame Shift Del (DEL) | VAF 21/66 reads (32%) | called by mutect2, pindel, varscan2
- NKTR | c.1287del p.K429Nfs*37 | Frame Shift Del (DEL) | VAF 16/77 reads (21%) | called by mutect2, pindel, varscan2
- NLGN2 | c.1262C>T p.P421L | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- OTOGL | c.1759del p.T587Pfs*5 (on ENST00000547103; = p.T578Pfs*5 on NM_173591.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | called by mutect2, pindel, varscan2
- PAPPA2 | c.4586dup p.I1530Yfs*26 | Frame Shift Ins (INS) | VAF 13/62 reads (21%) | called by mutect2, pindel, varscan2
- PCDH9 | c.2220dup p.P741Tfs*5 | Frame Shift Ins (INS) | VAF 13/100 reads (13%) | called by mutect2, pindel, varscan2
- PDGFRA | c.2684del p.P895Lfs*5 | Frame Shift Del (DEL) | VAF 24/59 reads (41%) | called by mutect2, pindel, varscan2
- PDS5A | c.85dup p.V29Gfs*34 | Frame Shift Ins (INS) | VAF 27/79 reads (34%) | called by mutect2, pindel, varscan2
- PLCB4 | c.353del p.N118Ifs*4 | Frame Shift Del (DEL) | VAF 11/96 reads (11%) | called by mutect2, pindel, varscan2
- PRDM1 | c.1361del p.G454Afs*52 | Frame Shift Del (DEL) | VAF 16/51 reads (31%) | called by mutect2, pindel, varscan2
- PRKACB | c.1029del p.K343Nfs*17 | Frame Shift Del (DEL) | VAF 18/74 reads (24%) | called by mutect2, pindel, varscan2
- PSAPL1 | c.1072_1074del p.K358del | In Frame Del (DEL) | VAF 25/66 reads (38%) | called by mutect2, pindel, varscan2
- RNF43 | c.1357_1358dup p.R454Nfs*49 | Frame Shift Ins (INS) | VAF 25/57 reads (44%) | called by mutect2, pindel, varscan2
- RUSC2 | c.1461del p.N488Tfs*31 | Frame Shift Del (DEL) | VAF 20/76 reads (26%) | called by mutect2, pindel, varscan2
- SCN10A | c.2124del p.F708Lfs*32 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | called by mutect2, pindel, varscan2
- SCN9A | c.5157dup p.V1720Sfs*8 (on ENST00000303354; = p.V1709Sfs*8 on NM_002977.3) | Frame Shift Ins (INS) | VAF 46/174 reads (26%) | called by mutect2, varscan2
- SIGLEC1 | c.954del p.I319Sfs*12 | Frame Shift Del (DEL) | VAF 6/57 reads (11%) | called by mutect2, pindel
- SLC22A4 | c.1513del p.L505Ffs*9 | Frame Shift Del (DEL) | VAF 28/139 reads (20%) | called by mutect2, pindel, varscan2
- SLC37A1 | c.1091del p.K364Rfs*22 | Frame Shift Del (DEL) | VAF 5/31 reads (16%) | called by mutect2, pindel, varscan2
- SLC9C2 | c.1406dup p.L469Ffs*5 | Frame Shift Ins (INS) | VAF 8/50 reads (16%) | called by mutect2, pindel, varscan2
- SNTB1 | c.389del p.G130Afs*34 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- SORBS3 | c.1693dup p.R565Pfs*13 | Frame Shift Ins (INS) | VAF 6/32 reads (19%) | called by mutect2, pindel
- SOX12 | c.879del p.E294Rfs*5 | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | called by mutect2, pindel
- SPATA16 | c.1198dup p.I400Nfs*13 | Frame Shift Ins (INS) | VAF 17/86 reads (20%) | called by mutect2, pindel, varscan2
- SPATC1 | c.1461_1462del p.S488* | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | called by mutect2, pindel, varscan2
- SURF2 | c.479del p.G160Efs*8 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | called by mutect2, pindel, varscan2
- SYNE2 | c.3609_3610del p.E1205Afs*6 | Frame Shift Del (DEL) | VAF 18/77 reads (23%) | called by mutect2, pindel, varscan2
- TAAR1 | c.378_379del p.C126* | Nonsense Mutation (DEL) | VAF 8/46 reads (17%) | called by pindel, varscan2
- TIAL1 | c.824del p.G275Vfs*7 | Frame Shift Del (DEL) | VAF 11/63 reads (17%) | called by mutect2, pindel, varscan2
- TLE3 | c.843dup p.D282Rfs*14 | Frame Shift Ins (INS) | VAF 4/18 reads (22%) | called by pindel, varscan2
- TP53BP1 | c.1099_1101del p.P367del | In Frame Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- TRAV13-1 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTN | c.75295dup p.T25099Nfs*4 (on ENST00000591111; = p.T17675Nfs*4 on NM_003319.4) | Frame Shift Ins (INS) | VAF 22/95 reads (23%) | called by mutect2, pindel, varscan2
- USP42 | c.2447del p.P816Lfs*9 | Frame Shift Del (DEL) | VAF 6/53 reads (11%) | called by mutect2, pindel
- WDR91 | c.2001dup p.R668Qfs*8 | Frame Shift Ins (INS) | VAF 37/121 reads (31%) | called by mutect2, pindel, varscan2
- XRCC2 | c.350del p.L117Wfs*17 | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | called by mutect2, varscan2
- XRN2 | c.2364dup p.S789Ifs*14 | Frame Shift Ins (INS) | VAF 21/122 reads (17%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.7939del p.R2647Gfs*44 | Frame Shift Del (DEL) | VAF 7/49 reads (14%) | called by mutect2, pindel, varscan2
- ZNF791 | c.1707del p.K569Nfs*3 | Frame Shift Del (DEL) | VAF 26/97 reads (27%) | called by mutect2, pindel, varscan2
- A2ML1 | c.3222C>T p.G1074= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV100229318; called by muse, mutect2, varscan2
- ABCA1 | c.6321T>C p.C2107= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV101037504; called by muse, mutect2, varscan2
- ABCB1 | c.2226T>C p.I742= | Silent (SNP) | VAF 26/120 reads (22%) | catalogued as COSV99714034; called by muse, mutect2, varscan2
- ADGRB3 | c.3072T>C p.A1024= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV53248722; called by muse, varscan2
- AKR7A3 | c.562A>C p.R188= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV100853833; called by muse, mutect2, varscan2
- ALG10B | c.1053T>C p.N351= | Silent (SNP) | VAF 32/121 reads (26%) | catalogued as rs767876437, COSV100439972; called by muse, mutect2, varscan2
- ALS2 | c.54C>T p.G18= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV99969907; called by muse, mutect2, varscan2
- ANAPC1 | c.3132G>A p.A1044= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as rs1261560030; called by muse, mutect2, varscan2
- ARL4C | c.6C>T p.G2= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100327077; called by muse, mutect2, varscan2
- ASAP1 | c.2751G>A p.P917= | Silent (SNP) | VAF 32/125 reads (26%) | catalogued as rs377622334, COSV63044350; called by muse, mutect2, varscan2
- ASB2 | c.663C>A p.A221= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV100279549; called by muse, mutect2, varscan2
- ATR | c.5292C>T p.S1764= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as rs745745176, COSV63392245; called by muse, mutect2, varscan2
- BNIPL | c.1011A>G p.Q337= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV99764767; called by muse, mutect2, varscan2
- BTBD2 | c.495C>T p.D165= | Silent (SNP) | VAF 28/109 reads (26%) | catalogued as rs113648977; called by muse, mutect2, varscan2
- C10orf99 | c.33T>C p.C11= | Silent (SNP) | VAF 24/148 reads (16%) | catalogued as COSV100929367, COSV100929369; called by muse, mutect2, varscan2
- CADPS2 | c.1587G>A p.K529= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs1287990627, COSV100465224; called by mutect2, varscan2
- CAPN7 | c.2340G>A p.G780= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as rs1030315222, COSV99508497; called by muse, mutect2, varscan2
- CBX6 | c.498G>A p.P166= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99328265; called by mutect2, varscan2
- CCDC105 | c.1410G>A p.P470= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as rs906501792, COSV99480072; called by muse, mutect2
- CCDC80 | c.615C>T p.S205= | Silent (SNP) | VAF 35/73 reads (48%) | catalogued as COSV52819689; called by muse, mutect2, varscan2
- CCNB1IP1 | c.108T>C p.H36= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs780820004, COSV100738634; called by muse, mutect2, varscan2
- CD163L1 | c.1761C>T p.G587= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs926502193, COSV58011231; called by muse, mutect2
- CDH4 | c.2331C>T p.R777= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs377265888, COSV100849320; called by muse, mutect2, varscan2
- CEACAM5 | c.1950C>T p.N650= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as rs565105444, COSV55750962, COSV99703904; called by muse, mutect2, varscan2
- CEL | c.390C>T p.G130= (on ENST00000673714; = p.G127= on NM_001807.6) | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as rs369130237, COSV100672737; called by muse, mutect2, varscan2
- CELA3A | c.135C>T p.S45= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as COSV99266684; called by muse, varscan2
- CGREF1 | c.111G>A p.L37= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV99565376; called by muse, mutect2, varscan2
- CHRM3 | c.1752C>T p.R584= | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as rs201601302, COSV55085033; called by muse, mutect2, varscan2
- CLCNKB | c.774C>T p.S258= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as rs1200797674, COSV100990443; called by muse, mutect2, varscan2
- CLDN11 | c.243C>T p.C81= | Silent (SNP) | VAF 29/156 reads (19%) | catalogued as rs771849791, COSV99291073; called by muse, mutect2, varscan2
- COL17A1 | c.798C>T p.C266= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV100793306; called by muse, mutect2, varscan2
- COL1A1 | c.3330C>T p.H1110= | Silent (SNP) | VAF 30/121 reads (25%) | catalogued as COSV99867967; called by muse, mutect2, varscan2
- COL5A3 | c.3363G>A p.G1121= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV99319575; called by muse, mutect2
- CORO1B | c.1413C>T p.G471= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs530415676, COSV100396713; called by muse, varscan2
- CPA1 | c.357C>T p.Y119= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs782032191, COSV50568076; called by muse, mutect2
- CR1L | c.660A>G p.P220= | Silent (SNP) | VAF 16/199 reads (8%) | catalogued as rs560511652, COSV99687856; called by muse, mutect2
- CRAT | c.1179C>T p.I393= | Silent (SNP) | VAF 54/180 reads (30%) | catalogued as rs1198735780, COSV58877087; called by muse, mutect2, varscan2
- CRYBA2 | c.240C>A p.A80= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV99838138; called by muse, mutect2, varscan2
- CYP2C18 | c.1137C>T p.Y379= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as COSV53674148; called by muse, mutect2, varscan2
- DDR1 | c.2307G>A p.T769= (on ENST00000324771; = p.T732= on NM_001954.4) | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs748824831, COSV100241655; called by muse, mutect2, varscan2
- DHRS7C | c.639C>T p.Y213= (on ENST00000330255 / NM_001220493.2; = p.Y212= on NM_001105571.3) | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs755563660, COSV57650928; called by muse, mutect2, varscan2
- DICER1 | c.1257T>C p.D419= | Silent (SNP) | VAF 37/108 reads (34%) | catalogued as COSV100602443; called by muse, mutect2, varscan2
- DIP2C | c.1872C>T p.N624= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV99793367; called by muse, mutect2
- DIPK1B | c.972C>A p.T324= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV100765493; called by muse, mutect2, varscan2
- DLGAP5 | c.2304T>A p.P768= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV99904109; called by muse, mutect2, varscan2
- DNAH3 | c.4734C>T p.L1578= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs896659486, COSV99769930; called by muse, mutect2
- DNAI2 | c.1326C>T p.C442= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs537816710, COSV56761011; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAJC1 | c.1584G>A p.P528= | Silent (SNP) | VAF 27/145 reads (19%) | catalogued as rs188868921, COSV65409784; called by muse, mutect2, varscan2
- EGR3 | c.675T>C p.I225= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV100416254; called by muse, mutect2, varscan2
- EMILIN2 | c.2913G>T p.S971= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs143370108, COSV99598818; called by muse, mutect2, varscan2
- EPHA10 | c.2499C>T p.G833= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV100361650; called by muse, mutect2
- ERC2 | c.729G>A p.Q243= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as rs1189001998, COSV99888448; called by muse, mutect2, varscan2
- EXOC3L1 | c.432G>A p.P144= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as rs375726014; called by muse, mutect2, varscan2
- FGFR4 | c.1656C>T p.C552= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs528265762, COSV52805812; called by muse, mutect2, varscan2
- FNDC1 | c.1959T>C p.A653= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV99796499; called by muse, mutect2, varscan2
- FNIP1 | c.1761A>G p.T587= | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as COSV100330568; called by muse, mutect2, varscan2
- GPHN | c.2157C>T p.Y719= (on ENST00000315266 / NM_001377519.1; = p.Y752= on NM_020806.5) | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs1443875641, COSV100017414; called by muse, mutect2, varscan2
- GUSB | c.1212C>T p.I404= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as rs375214425, COSV100512736; called by muse, mutect2, varscan2
- HHIP | c.255G>A p.P85= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs202159669, COSV56843525, COSV99667538; called by muse, mutect2, varscan2
- HIVEP1 | c.6639G>A p.P2213= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs760534569, COSV101045626; called by muse, mutect2, varscan2
- HOXC4 | c.720G>T p.P240= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV57699584; called by muse, mutect2, varscan2
- HSPA6 | c.804C>A p.A268= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV100554282; called by muse, mutect2
- IKBKB | c.651G>A p.T217= | Silent (SNP) | VAF 38/129 reads (29%) | catalogued as rs1280519569, COSV60595767, COSV60595934; called by muse, mutect2, varscan2
- IPO13 | c.1086C>A p.T362= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as COSV100961326; called by muse, mutect2, varscan2
- IQCD | c.18C>T p.L6= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV55321175; called by muse, mutect2, varscan2
- IQGAP2 | c.1242C>T p.N414= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV99167880; called by muse, mutect2, varscan2
- IRF9 | c.519A>G p.G173= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100138253; called by muse, mutect2
- IRGC | c.279G>A p.T93= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs1001768317, COSV54985658; called by muse, mutect2, varscan2
- ISX | c.72G>A p.P24= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs147323979; called by muse, mutect2, varscan2
- ITIH2 | c.2760C>T p.H920= | Silent (SNP) | VAF 36/189 reads (19%) | catalogued as COSV100623385, COSV64431968; called by muse, mutect2, varscan2
- ITPR2 | c.5679C>T p.C1893= | Silent (SNP) | VAF 22/164 reads (13%) | catalogued as COSV101190122; called by muse, mutect2, varscan2
- KIAA0319L | c.711G>A p.L237= | Silent (SNP) | VAF 36/119 reads (30%) | catalogued as COSV100357631; called by muse, mutect2, varscan2
- KIAA1109 | c.7971A>G p.S2657= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV99170111; called by muse, mutect2, varscan2
- KIF1A | c.3258G>A p.P1086= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as rs375702153; called by muse, mutect2, varscan2
- KIF26A | c.2025G>A p.P675= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs1184128383; called by muse, mutect2, varscan2
117 further variants in this file (0 protein-altering or splice-affecting, 93 silent, 24 other) are not listed here.
